Somatic mutation profile of tumor specimen TCGA-06-A6S1-01A (aliquot TCGA-06-A6S1-01A-11D-A33T-08) from TCGA case TCGA-06-A6S1, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 53.2 years (19,443 days).
Specimen TCGA-06-A6S1-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 78c8365a-94d2-4101-96fa-beb6a6fd44d9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-06-A6S1-10A (Blood Derived Normal), aliquot TCGA-06-A6S1-10A-01D-A33W-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ac305450-994f-47e3-9196-341b3e8f21f3

The open-access MAF lists 46 somatic variants for this specimen: 38 protein-altering or splice-affecting, 8 silent.
By variant classification: Missense Mutation 31, Silent 8, Nonsense Mutation 3, Splice Site 2, Frame Shift Del 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.664C>T p.R222C | Missense Mutation (SNP) | VAF 82/1302 reads (6%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51784086; called by muse, mutect2
- AGRN | c.4501G>A p.D1501N | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT deleterious (0.05); PolyPhen benign (0.025); catalogued as COSV101038788; called by muse, mutect2, varscan2
- ASAP1 | c.6A>T p.R2S | Missense Mutation (SNP) | VAF 25/64 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.879); catalogued as rs1565285711, COSV100727137; called by muse, mutect2, varscan2
- BMP1 | c.1706G>T p.S569I | Missense Mutation (SNP) | VAF 16/74 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as COSV100109446; called by muse, mutect2, varscan2
- CAPRIN2 | c.595C>T p.Q199* | Nonsense Mutation (SNP) | VAF 26/87 reads (30%) | catalogued as COSV99195482; called by muse, mutect2, varscan2
- CBLB | c.2167C>T p.P723S | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.003); catalogued as COSV99913290; called by muse, mutect2, varscan2
- CCDC178 | c.1151del p.N384Mfs*13 | Frame Shift Del (DEL) | VAF 4/36 reads (11%) | catalogued as rs749875431; called by mutect2, pindel
- CENPC | c.989G>A p.R330H | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs371671240, COSV56623034; called by muse, mutect2, varscan2
- CLP1 | c.233G>A p.R78H | Missense Mutation (SNP) | VAF 13/64 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.346); catalogued as rs752132257, COSV57054362; called by muse, mutect2, varscan2
- COL4A6 | c.3496G>T p.G1166C | Missense Mutation (SNP) | VAF 39/245 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57883472; called by muse, mutect2, varscan2
- DBF4 | c.1627C>G p.L543V | Missense Mutation (SNP) | VAF 16/148 reads (11%) | SIFT tolerated (0.47); PolyPhen benign (0.009); catalogued as COSV99719262; called by muse, mutect2, varscan2
- DDR2 | c.2505T>G p.D835E | Missense Mutation (SNP) | VAF 12/107 reads (11%) | SIFT tolerated (0.26); PolyPhen benign (0.052); catalogued as COSV100906471; called by muse, mutect2, varscan2
- EGFR | c.2320G>A p.V774M | Missense Mutation (SNP) | VAF 66/874 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs567477136, COSV51777313, COSV51843665; called by muse, mutect2
- ELP4 | c.631T>G p.S211A (on ENST00000350638; = p.S210A on NM_019040.5) | Missense Mutation (SNP) | VAF 22/70 reads (31%) | SIFT tolerated (0.12); PolyPhen benign (0.005); catalogued as COSV100635378; called by muse, mutect2, varscan2
- ENPP7 | c.569T>C p.L190P | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1555823261, COSV100093347; called by muse, mutect2, varscan2
- GCM2 | c.509C>T p.A170V | Missense Mutation (SNP) | VAF 11/86 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.18); catalogued as COSV101069500; called by muse, mutect2, varscan2
- IL5RA | c.995-1G>T p.X332_splice | Splice Site (SNP) | VAF 10/41 reads (24%) | catalogued as COSV99842916; called by muse, mutect2
- JSRP1 | c.766C>T p.P256S | Missense Mutation (SNP) | VAF 28/86 reads (33%) | SIFT tolerated (0.18); PolyPhen benign (0.026); catalogued as COSV99677786; called by muse, mutect2, varscan2
- KIF5C | c.1529G>C p.R510P | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.37); catalogued as COSV101276126; called by muse, mutect2
- KRT14 | c.495C>G p.Y165* | Nonsense Mutation (SNP) | VAF 36/148 reads (24%) | catalogued as COSV99390989; called by muse, mutect2, varscan2
- LPAR4 | c.199C>T p.R67C | Missense Mutation (SNP) | VAF 26/172 reads (15%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.91); catalogued as rs767013097, COSV70913314; called by muse, mutect2, varscan2
- MARCHF10 | c.755C>T p.S252L | Missense Mutation (SNP) | VAF 52/160 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs900772304, COSV60887191; called by muse, mutect2, varscan2
- MASTL | c.1312C>A p.L438I | Missense Mutation (SNP) | VAF 30/63 reads (48%) | SIFT tolerated (0.11); PolyPhen benign (0.009); catalogued as COSV100668875, COSV60909334; called by muse, mutect2, varscan2
- MKS1 | c.590T>C p.I197T | Missense Mutation (SNP) | VAF 7/94 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.122); catalogued as COSV100439579; called by muse, mutect2
- MTMR8 | c.788A>G p.Y263C | Missense Mutation (SNP) | VAF 15/77 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100878426; called by muse, mutect2, varscan2
- OR52B2 | c.181A>T p.M61L | Missense Mutation (SNP) | VAF 8/111 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.219); catalogued as rs906891034, COSV101603941; called by muse, mutect2
- OR8D1 | c.164T>C p.L55P | Missense Mutation (SNP) | VAF 29/96 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.32); catalogued as COSV100766619; called by muse, mutect2, varscan2
- OR8G2P | c.353C>T p.T118M | Missense Mutation (SNP) | VAF 46/175 reads (26%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs566362808; called by muse, mutect2, varscan2
- PPM1J | c.1436G>A p.R479H | Missense Mutation (SNP) | VAF 20/85 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as rs113935705; called by muse, mutect2, varscan2
- SYVN1 | c.902G>C p.G301A | Missense Mutation (SNP) | VAF 33/111 reads (30%) | SIFT tolerated (0.45); PolyPhen benign (0.066); catalogued as COSV99589074; called by muse, mutect2, varscan2
- TM6SF1 | c.370C>A p.L124M | Missense Mutation (SNP) | VAF 34/135 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1411428038, COSV99362603; called by muse, mutect2, varscan2
- USP9X | c.7534G>A p.A2512T | Missense Mutation (SNP) | VAF 9/65 reads (14%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0); catalogued as rs1476832053, COSV100199001; called by muse, mutect2, varscan2
- ZFHX4 | c.4960A>C p.S1654R | Missense Mutation (SNP) | VAF 30/78 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.398); catalogued as COSV51492586, COSV99261788; called by muse, mutect2, varscan2
- ZNF574 | c.202C>G p.Q68E | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT tolerated (0.46); PolyPhen possibly damaging (0.857); catalogued as COSV99726021; called by muse, mutect2, varscan2
- ZNF808 | c.1414C>T p.R472* | Nonsense Mutation (SNP) | VAF 18/67 reads (27%) | catalogued as rs759909491, COSV100707894; called by muse, mutect2, varscan2
- KATNIP | c.2624-1_2624del p.X875_splice | Splice Site (DEL) | VAF 18/178 reads (10%) | called by pindel, varscan2
- SPACA5B | c.148C>A p.L50M | Missense Mutation (SNP) | VAF 18/113 reads (16%) | SIFT tolerated (0.45); PolyPhen benign (0.363); called by muse, mutect2, varscan2
- STAG2 | c.1873_1874del p.D625Yfs*9 | Frame Shift Del (DEL) | VAF 17/84 reads (20%) | called by mutect2, pindel, varscan2
- ALG13 | c.2334G>A p.L778= | Silent (SNP) | VAF 10/37 reads (27%) | catalogued as COSV99322058; called by muse, mutect2, varscan2
- CCDC171 | c.1270T>C p.L424= | Silent (SNP) | VAF 36/101 reads (36%) | catalogued as COSV99900409; called by muse, mutect2, varscan2
- DLGAP2 | c.354G>A p.P118= | Silent (SNP) | VAF 4/9 reads (44%) | catalogued as COSV70105023; called by muse, mutect2, varscan2
- GPR50 | c.1668C>T p.D556= | Silent (SNP) | VAF 18/145 reads (12%) | catalogued as rs747548013, COSV54441311; called by muse, mutect2, varscan2
- GSPT2 | c.315A>T p.G105= | Silent (SNP) | VAF 4/18 reads (22%) | catalogued as COSV100468116; called by muse, mutect2
- RAPSN | c.741C>G p.L247= | Silent (SNP) | VAF 4/12 reads (33%) | catalogued as rs747387595, COSV100100113, COSV54085111; called by muse, mutect2
- SPTBN2 | c.246C>T p.Y82= | Silent (SNP) | VAF 16/45 reads (36%) | catalogued as rs913968578, COSV100019078; called by muse, mutect2, varscan2
- TGM2 | c.702G>A p.Q234= | Silent (SNP) | VAF 25/63 reads (40%) | catalogued as COSV100821591; called by muse, mutect2, varscan2
